Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A65V, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A65V-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: F

Age:

Date of surgery:

Localisation: frontal lobe

Diagnosis: Oligodendroglioma (grade 2 WHO)

Name of Pathologist:

ICD-O-3
Oligodendroglioma NOS
Path 9450/3
Site Brain, frontal lobe
C71.1
CSF Brain, supratentorial
C71.0
JW 4/19/13

Source: NCI Genomic Data Commons file c8d8fd77-e18f-4704-9999-83dac3a0e84f (TCGA-QH-A65V.32E7C9B3-CC0B-4D62-9798-F48CDD2A1746.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).